Somatic mutation profile of tumor specimen TCGA-AA-A02R-01A (aliquot TCGA-AA-A02R-01A-01W-A00E-09) from TCGA case TCGA-AA-A02R, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 84.4 years (30,834 days).
Specimen TCGA-AA-A02R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2488e9ef-a626-4ef3-a0f0-d0a2129832be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A02R-10A (Blood Derived Normal), aliquot TCGA-AA-A02R-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9c78e71-942a-45bc-a4fd-bbf7cec8c23e

The open-access MAF lists 1,412 somatic variants for this specimen: 1,096 protein-altering or splice-affecting, 293 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 685, Silent 293, Frame Shift Del 284, Nonsense Mutation 49, Frame Shift Ins 38, Splice Site 15, Splice Region 13, In Frame Del 10, RNA 9, Intron 9, 3'UTR 2, 5'Flank 1.

Variants (750 of 1,412; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- BIVM-ERCC5 | c.4113del p.K1371Nfs*65 | Frame Shift Del (DEL) | VAF 35/132 reads (27%) | catalogued as rs752661599, COSV100863757; ClinVar: pathogenic; called by mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 36/100 reads (36%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/159 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDH1 | c.1137G>A p.T379= | Splice Region (SNP) | VAF 30/73 reads (41%) | catalogued as rs587783050, CS060517, COSV55733400; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EP300 | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 30/82 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519889, COSV54325045, COSV54326888, COSV54344606; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EXT1 | c.1468del p.L490Wfs*9 | Frame Shift Del (DEL) | VAF 36/86 reads (42%) | catalogued as rs886039355, CD000259; ClinVar: pathogenic; called by mutect2, varscan2
- F8 | c.6046C>T p.R2016W | Missense Mutation (SNP) | VAF 71/219 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852453, CM082650, CM910144, COSV64270541; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXL3 | c.884del p.L295Yfs*25 | Frame Shift Del (DEL) | VAF 33/71 reads (46%) | catalogued as rs764008859; ClinVar: pathogenic; called by mutect2, varscan2
- KANSL1 | c.779del p.G260Vfs*19 | Frame Shift Del (DEL) | VAF 58/220 reads (26%) | catalogued as rs748018297; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- KIF5A | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs121434444, CM060295, COSV54051972; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 21/100 reads (21%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- MPZ | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913589, CD103362, CM165580, CM960978, CM960979, COSV100337829; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 112/164 reads (68%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- SPINK5 | c.2468del p.K823Rfs*101 | Frame Shift Del (DEL) | VAF 34/65 reads (52%) | catalogued as rs565782662; ClinVar: pathogenic; called by mutect2, varscan2
- USH2A | c.13822C>T p.R4608* | Nonsense Mutation (SNP) | VAF 43/133 reads (32%) | catalogued as rs367674026, CM080601; ClinVar: pathogenic; called by muse, varscan2
- AARS2 | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs753428388; called by muse, varscan2
- AASDH | c.1319del p.L440Wfs*43 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs770970036; called by mutect2, varscan2
- AC005324.2 | c.449G>A p.C150Y | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV60886572; called by muse, mutect2
- ACAD11 | c.1819C>T p.R607* | Nonsense Mutation (SNP) | VAF 28/74 reads (38%) | catalogued as rs772764413, COSV99391621; called by muse, mutect2, varscan2
- ACAD9 | c.1009A>G p.S337G | Missense Mutation (SNP) | VAF 108/132 reads (82%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as rs201248046, COSV58307341; called by muse, mutect2, varscan2
- ACSF2 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs767097885; called by muse, mutect2, varscan2
- ADAD1 | c.244del p.I82Yfs*6 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | catalogued as rs746068816; called by mutect2, varscan2
- ADAM19 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178207005, COSV57436288; called by muse, mutect2, varscan2
- ADAMTS1 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs762654704, COSV99536347; called by muse, mutect2, varscan2
- ADAMTS6 | c.1826C>T p.T609I | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.12); catalogued as COSV66856976; called by muse, mutect2, varscan2
- ADAMTS9 | c.284C>A p.S95Y | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99898397; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3871G>A p.D1291N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.978); catalogued as rs779376771; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 55/178 reads (31%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRG4 | c.6955G>A p.A2319T | Missense Mutation (SNP) | VAF 90/274 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.48); catalogued as COSV99794875; called by muse, mutect2, varscan2
- ADGRL2 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV54665311; called by muse, mutect2, varscan2
- ADNP2 | c.971del p.P324Lfs*8 | Frame Shift Del (DEL) | VAF 24/42 reads (57%) | catalogued as rs772825390; called by mutect2, varscan2
- ADPGK | c.400A>G p.S134G | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs1267290633; called by muse, mutect2, varscan2
- AGGF1 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs772128053; called by muse, mutect2, varscan2
- AGTPBP1 | c.2798C>T p.T933M (on ENST00000357081 / NM_001330701.2; = p.T893M on NM_015239.2) | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61268602; called by muse, mutect2, varscan2
- AIDA | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV60663782; called by muse, mutect2, varscan2
- AKAP3 | c.590G>A p.G197D | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1431564219; called by muse, mutect2
- AKAP4 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV62074325; called by muse, mutect2, varscan2
- AKAP6 | c.31del p.L11* | Frame Shift Del (DEL) | VAF 42/119 reads (35%) | catalogued as rs771895850; called by mutect2, pindel, varscan2
- AKAP6 | c.6002C>T p.A2001V | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs371577987; called by muse, mutect2, varscan2
- AL592490.1 | c.2727A>G p.I909M | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV69426052; called by muse, mutect2, varscan2
- ALPK1 | c.958T>A p.L320M | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs757602009; called by muse, mutect2, varscan2
- ALPK2 | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs142220132; called by muse, mutect2, varscan2
- ANK3 | c.2147T>A p.L716H | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55056078; called by muse, mutect2, varscan2
- ANKHD1 | c.3551+2T>C p.X1184_splice | Splice Site (SNP) | VAF 48/148 reads (32%) | catalogued as COSV51846067; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5900C>A p.P1967H | Missense Mutation (SNP) | VAF 78/238 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV51854763; called by muse, mutect2, varscan2
- ANTXR1 | c.311A>G p.Q104R | Missense Mutation (SNP) | VAF 67/214 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV58013033; called by muse, mutect2, varscan2
- ANXA9 | c.376C>A p.L126M | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as COSV100929078; called by muse, mutect2, varscan2
- AOC1 | c.626G>A p.G209D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.441); catalogued as rs752440416; called by muse, mutect2
- AP2A2 | c.170del p.K57Sfs*24 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs753029866; called by mutect2, varscan2
- AP2M1 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs1313715106; called by muse, mutect2, varscan2
- AQP8 | c.363del p.M122Cfs*10 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs759782104; called by mutect2, varscan2
- ARFGEF3 | c.1687G>A p.V563M | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753166471, COSV52451136; called by muse, mutect2, varscan2
- ARHGAP18 | c.488del p.N163Tfs*55 | Frame Shift Del (DEL) | VAF 46/146 reads (32%) | catalogued as rs749346165; called by mutect2, varscan2
- ARHGAP21 | c.3226C>T p.R1076C | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs757997943, COSV100256540; called by muse, mutect2, varscan2
- ARHGEF40 | c.4245C>T p.A1415= | Splice Region (SNP) | VAF 9/22 reads (41%) | catalogued as rs376417932; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 40/119 reads (34%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARSJ | c.1737del p.K580Rfs*29 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | catalogued as COSV100193266; called by mutect2, pindel, varscan2
- ARSK | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 101/275 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1487153898; called by muse, mutect2, varscan2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 42/117 reads (36%) | catalogued as rs747570359; called by mutect2, varscan2
- ASTN1 | c.1345T>G p.F449V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV56087061; called by muse, mutect2, varscan2
- ATAD5 | c.1336dup p.I446Nfs*21 | Frame Shift Ins (INS) | VAF 48/171 reads (28%) | catalogued as rs1215252375; called by mutect2, varscan2
- ATN1 | c.764del p.P255Hfs*43 | Frame Shift Del (DEL) | VAF 36/72 reads (50%) | catalogued as rs1555143544, COSV63112070; called by mutect2, varscan2
- ATP10B | c.3790A>G p.M1264V | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs762967777; called by muse, mutect2, varscan2
- ATP11A | c.1471G>T p.G491C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52110875, COSV52125914; called by muse, mutect2, varscan2
- ATP13A3 | c.3079dup p.W1027Lfs*9 | Frame Shift Ins (INS) | VAF 26/82 reads (32%) | catalogued as rs746602775; called by mutect2, varscan2
- ATP7B | c.3451C>A p.R1151S | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM076004, CM164053, COSV54438170; called by muse, mutect2, varscan2
- ATP9A | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as rs752675481; called by muse, mutect2, varscan2
- ATRX | c.6064C>A p.L2022I | Missense Mutation (SNP) | VAF 75/232 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.503); catalogued as CM062433, COSV64875909; called by muse, mutect2, varscan2
- BAG2 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as COSV58097825; called by muse, mutect2, varscan2
- BBS9 | c.1965A>G p.L655= (on ENST00000242067 / NM_001348036.1; = p.L615= on NM_014451.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 155/505 reads (31%) | catalogued as COSV54177920; called by muse, mutect2, varscan2
- BCAN | c.1421T>A p.V474E | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1267696680; called by muse, varscan2
- BCAS1 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs148582842; called by muse, mutect2, varscan2
- BCL2A1 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 73/211 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs1353033250, COSV51212981; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 18/38 reads (47%) | catalogued as rs768244116; called by mutect2, pindel
- BDKRB1 | c.569T>C p.I190T | Missense Mutation (SNP) | VAF 460/486 reads (95%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as COSV99387737; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4898C>T p.A1633V | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT tolerated, low confidence (0.35); catalogued as rs998046185, COSV63245748; called by muse, mutect2, varscan2
- BMERB1 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1405481702, COSV100252723; called by muse, mutect2, varscan2
- BMPER | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 45/116 reads (39%) | catalogued as rs144985513; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 60/174 reads (34%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BRAP | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 52/80 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs989023764, COSV59535691; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 40/102 reads (39%) | catalogued as rs749043197; called by mutect2, varscan2
- BUB1 | c.2471A>C p.K824T | Missense Mutation (SNP) | VAF 77/228 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57067173; called by muse, mutect2, varscan2
- C10orf90 | c.1449del p.P484Lfs*22 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | catalogued as rs1564811005; called by mutect2, pindel, varscan2
- C10orf90 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs138339872, COSV52956297; called by muse, mutect2
- C1QTNF3 | c.11G>T p.R4M | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.06); catalogued as COSV51468497; called by muse, mutect2, varscan2
- C20orf194 | c.3463C>T p.R1155W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs377127941; called by muse, mutect2
- C5AR1 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.464); catalogued as rs201037165; called by muse, mutect2, varscan2
- C9orf78 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs139248631, COSV100989965; called by muse, mutect2
- CACNA1D | c.3953del p.F1318Sfs*6 (on ENST00000350061 / NM_001128840.3; = p.F1338Sfs*6 on NM_000720.4) | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | catalogued as COSV55445773; called by mutect2, pindel, varscan2
- CACNA1E | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1383093652, COSV100702593; called by muse, mutect2, varscan2
- CARF | c.897del p.V300Sfs*55 | Frame Shift Del (DEL) | VAF 88/277 reads (32%) | catalogued as rs751635415; called by mutect2, pindel, varscan2
- CASP4 | c.231del p.F77Lfs*3 | Frame Shift Del (DEL) | VAF 112/290 reads (39%) | catalogued as rs779092072; called by mutect2, varscan2
- CAV3 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs776563500; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CBLL2 | c.892T>C p.Y298H | Missense Mutation (SNP) | VAF 155/410 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.095); catalogued as rs1330441699; called by muse, mutect2, varscan2
- CCAR2 | c.1249del p.R417Gfs*89 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs756536005; called by mutect2, varscan2
- CCDC18 | c.1802dup p.N601Kfs*13 (on ENST00000343253 / NM_001306076.1; = p.N602Kfs*13 on NM_206886.4) | Frame Shift Ins (INS) | VAF 32/99 reads (32%) | catalogued as rs1557640875; called by mutect2, varscan2
- CCDC60 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs748209413, COSV59547456; called by muse, mutect2, varscan2
- CCDC62 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV53433019; called by muse, mutect2, varscan2
- CCNL1 | c.959T>C p.L320S | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as COSV55819174; called by muse, mutect2, varscan2
- CCR3 | c.701del p.K234Sfs*52 | Frame Shift Del (DEL) | VAF 26/105 reads (25%) | catalogued as rs761073142; called by mutect2, varscan2
- CCT4 | c.967A>G p.M323V | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as rs140356041; called by muse, mutect2, varscan2
- CD5L | c.323A>G p.Q108R | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs776618787, COSV63821874; called by muse, mutect2, varscan2
- CDC14B | c.907T>C p.C303R | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99684993; called by muse, mutect2, varscan2
- CDCA7L | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as rs1366267269; called by muse, mutect2, varscan2
- CDH13 | c.304dup p.H102Pfs*25 | Frame Shift Ins (INS) | VAF 10/23 reads (43%) | catalogued as rs752068202; called by pindel, varscan2
- CDH13 | c.343A>G p.K115E | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs764273398; called by muse, varscan2
- CDH2 | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs754165315, COSV52276234, COSV52294881; called by muse, mutect2, varscan2
- CEBPZ | c.2885-3del | Splice Region (DEL) | VAF 34/79 reads (43%) | catalogued as rs375852685; called by mutect2, varscan2
- CELA2A | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs758475502; called by muse, varscan2
- CEP128 | c.1382A>T p.Y461F | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs1309403177; called by muse, mutect2, varscan2
- CEP170 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV60506456; called by muse, mutect2, varscan2
- CEP41 | c.162dup p.D55Rfs*2 | Frame Shift Ins (INS) | VAF 72/265 reads (27%) | catalogued as rs781888984; called by mutect2, pindel, varscan2
- CERS4 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as rs775538437, COSV52166632; called by muse, mutect2, varscan2
- CES2 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs371064921; called by muse, mutect2
- CFTR | c.3037C>T p.P1013S | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs978796108; called by muse, mutect2, varscan2
- CHAT | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs372760913, CM095703; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD1L | c.128-2A>G p.X43_splice | Splice Site (SNP) | VAF 4/40 reads (10%) | catalogued as rs1553937154, COSV63615568; called by muse, mutect2
- CHD2 | c.2842C>T p.R948W | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs543203414, COSV67709302; called by muse, mutect2, varscan2
- CHD9 | c.7893del p.R2632Dfs*28 (on ENST00000398510 / NM_001382353.1; = p.R2616Dfs*28 on NM_025134.7) | Frame Shift Del (DEL) | VAF 34/112 reads (30%) | catalogued as rs1567694162; called by mutect2, pindel, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | catalogued as rs751548647; called by mutect2, varscan2
- CHSY1 | c.1569G>T p.K523N | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.167); catalogued as rs1380250969; called by muse, mutect2, varscan2
- CIRBP | c.49A>G p.T17A | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs11555031; called by muse, mutect2, varscan2
- CLASP1 | c.3859G>A p.D1287N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs753994205; called by muse, mutect2
- CLCA4 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as rs377252384; called by muse, mutect2, varscan2
- CLCN1 | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 102/288 reads (35%) | SIFT tolerated (0.99); PolyPhen benign (0.021); catalogued as rs139158852; called by muse, varscan2
- CLEC3A | c.364G>A p.A122T (on ENST00000651443; = p.A113T on NM_005752.6) | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs147323906; called by muse, mutect2, varscan2
- CLEC5A | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as COSV69397419; called by muse, varscan2
- CNGA4 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1437010296, COSV66005824; called by muse, mutect2, varscan2
- CNNM2 | c.1355del p.P452Hfs*7 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as COSV100881679; called by mutect2, varscan2
- CNTN1 | c.2419+2T>C p.X807_splice | Splice Site (SNP) | VAF 119/221 reads (54%) | catalogued as rs1268185899; called by muse, mutect2, varscan2
- CNTRL | c.1554G>T p.Q518H | Missense Mutation (SNP) | VAF 102/329 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV53046510; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | catalogued as rs374805044; called by mutect2, varscan2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 78/208 reads (38%) | catalogued as rs748995811; called by mutect2, varscan2
- COL12A1 | c.7378G>A p.V2460M | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1393650106; called by muse, mutect2, varscan2
- COL1A2 | c.2314G>T p.G772C | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as CM973120; called by muse, mutect2, varscan2
- COL28A1 | c.2691del p.V898Wfs*18 | Frame Shift Del (DEL) | VAF 38/112 reads (34%) | catalogued as rs766010947; called by mutect2, pindel, varscan2
- COQ7 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs777014954; called by muse, mutect2, varscan2
- CPB1 | c.47A>G p.H16R | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.368); catalogued as COSV51575754; called by muse, mutect2, varscan2
- CPEB4 | c.1766G>A p.R589Q | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54171505; called by muse, mutect2, varscan2
- CPLX4 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs752019452, COSV55313481; called by muse, mutect2, varscan2
- CRACD | c.1964del p.R655Pfs*22 | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | catalogued as COSV51715473; called by mutect2, varscan2
- CRADD | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 79/150 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.109); catalogued as rs768737669; called by muse, mutect2, varscan2
- CSAD | c.436G>A p.G146R (on ENST00000444623 / NM_001244705.2; = p.G173R on NM_015989.5) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753082648; called by muse, mutect2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 26/68 reads (38%) | catalogued as rs747437399; called by mutect2, pindel, varscan2
- CSMD3 | c.3355G>A p.D1119N (on ENST00000297405 / NM_001363185.1; = p.D1015N on NM_052900.3) | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1321134506, COSV52145893; called by muse, mutect2, varscan2
- CSNK2A2 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV52641828; called by muse, mutect2, varscan2
- CTNNBL1 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.143); catalogued as rs779142999, COSV63744226; called by muse, mutect2, varscan2
- CWC22 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs761676860, COSV55426364, COSV55433719; called by muse, mutect2, varscan2
- CXCL2 | c.308del p.N103Mfs*50 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as rs745343380; called by mutect2, pindel, varscan2
- CYP20A1 | c.903del p.K301Nfs*6 | Frame Shift Del (DEL) | VAF 36/110 reads (33%) | catalogued as rs778884333; called by mutect2, varscan2
- CYP4F3 | c.394C>A p.L132M | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1568394600, COSV99658824; called by muse, mutect2, varscan2
- DCAF12L1 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs1418181235, COSV64421761; called by muse, mutect2, varscan2
- DCD | c.10A>G p.M4V | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); catalogued as rs1401300826; called by muse, mutect2, varscan2
- DCLK3 | c.327del p.R110Gfs*69 | Frame Shift Del (DEL) | VAF 42/137 reads (31%) | catalogued as COSV101373865, COSV69362732; called by mutect2, pindel, varscan2
- DCLRE1C | c.767G>A p.C256Y (on ENST00000378278 / NM_001350965.2; = p.C141Y on NM_022487.4) | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63184462; called by muse, mutect2, varscan2
- DCSTAMP | c.19G>T p.G7C | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); catalogued as COSV52577466; called by muse, mutect2, varscan2
- DDI1 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1409890817, COSV56392671; called by muse, mutect2, varscan2
- DDX39A | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV54393585; called by muse, mutect2
- DDX55 | c.1600del p.M534* | Frame Shift Del (DEL) | VAF 20/104 reads (19%) | catalogued as COSV53015309; called by mutect2, pindel, varscan2
- DELE1 | c.359G>T p.W120L | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV52005473; called by muse, mutect2
- DENND5A | c.2684del p.K895Sfs*7 | Frame Shift Del (DEL) | VAF 67/237 reads (28%) | catalogued as rs1208100549; called by mutect2, pindel, varscan2
- DHRS1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs559917499, COSV55384583; called by muse, mutect2, varscan2
- DHX15 | c.1981C>T p.R661C | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61026769; called by muse, mutect2, varscan2
- DHX15 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV61026777; called by muse, mutect2, varscan2
- DIO2 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1170347875; called by muse, mutect2, varscan2
- DISP3 | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1388520984, COSV53838243; called by muse, mutect2, varscan2
- DLG2 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 124/303 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs888845634; called by muse, mutect2, varscan2
- DMTF1 | c.1244del p.N415Tfs*28 | Frame Shift Del (DEL) | VAF 40/160 reads (25%) | catalogued as rs1348399160; called by mutect2, pindel, varscan2
- DNAAF4 | c.430del p.I144* | Frame Shift Del (DEL) | VAF 15/68 reads (22%) | catalogued as rs755135568; called by mutect2, pindel, varscan2
- DNAH10 | c.10292G>A p.R3431H (on ENST00000409039; = p.R3370H on NM_207437.3) | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157060583, COSV68992403; called by muse, mutect2, varscan2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 30/115 reads (26%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAH7 | c.3221del p.L1074Cfs*23 | Frame Shift Del (DEL) | VAF 52/145 reads (36%) | catalogued as rs763352877; called by mutect2, varscan2
- DNAJB14 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV62032681; called by muse, mutect2, varscan2
- DNAJC13 | c.236del p.K79Sfs*5 | Frame Shift Del (DEL) | VAF 37/113 reads (33%) | catalogued as COSV99607580; called by mutect2, pindel, varscan2
- DNAJC5B | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs139910886; called by muse, mutect2, varscan2
- DOCK1 | c.5372C>T p.T1791M | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.093); catalogued as rs765740645; called by muse, varscan2
- DOCK10 | c.1122del p.D375Ifs*8 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs750262341; called by mutect2, varscan2
- DPH5 | c.453_455del p.K151del | In Frame Del (DEL) | VAF 26/96 reads (27%) | catalogued as rs773362571; called by pindel, varscan2
- DYNC1I2 | c.105del p.E36Kfs*34 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | catalogued as rs755197346; called by mutect2, varscan2
- DYRK2 | c.773G>A p.R258H (on ENST00000344096 / NM_006482.3; = p.R185H on NM_003583.4) | Missense Mutation (SNP) | VAF 98/187 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1394921227; called by muse, mutect2, varscan2
- DYSF | c.2684G>A p.G895D | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244026613, COSV50625239; called by muse, mutect2, varscan2
- EEA1 | c.1360_1362del p.Q454del | In Frame Del (DEL) | VAF 35/218 reads (16%) | catalogued as rs773755370; called by pindel, varscan2
- EEF1AKNMT | c.1669G>A p.A557T (on ENST00000361735 / NM_015935.5; = p.A471T on NM_014955.3) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs772705665; called by muse, mutect2, varscan2
- EFL1 | c.2992C>T p.R998* | Nonsense Mutation (SNP) | VAF 125/321 reads (39%) | catalogued as rs1377271871, COSV51602584; called by muse, mutect2, varscan2
- EIF2AK1 | c.1598G>A p.R533Q | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52239792; called by muse, mutect2, varscan2
- ELK1 | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55952772; called by muse, mutect2, varscan2
- ELOA2 | c.2074G>A p.G692S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV55295931; called by muse, mutect2
- EMC3 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.037); catalogued as rs761023207; called by muse, mutect2, varscan2
- EPB41L1 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.733); catalogued as rs978010310, COSV52437534; called by muse, mutect2, varscan2
- EPG5 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as rs369502506; called by muse, varscan2
- ERV3-1 | c.38T>C p.L13S | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious, low confidence (0.03); catalogued as COSV51427400; called by muse, mutect2, varscan2
- ETS2 | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1433831363, COSV62872852; called by muse, mutect2, varscan2
- EVC2 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 356/970 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs774976776, COSV60387538; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F11R | c.179T>C p.V60A | Missense Mutation (SNP) | VAF 115/162 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs373771702; called by muse, mutect2, varscan2
- FAM135B | c.3700C>T p.R1234W | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757525959, COSV52703914, COSV52737505; called by muse, mutect2, varscan2
- FAM13A | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 65/111 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99983286; called by muse, mutect2, varscan2
- FAM13C | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as rs369435988; called by muse, mutect2, varscan2
- FAM162B | c.188T>C p.V63A | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV63920289; called by muse, mutect2, varscan2
- FAM186B | c.1318A>G p.K440E | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as rs1371039112; called by muse, mutect2, varscan2
- FANCL | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs769425665, CM1512822, COSV52072429; called by muse, mutect2, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 42/114 reads (37%) | catalogued as rs746983128; called by mutect2, varscan2
- FASLG | c.422del p.K141Rfs*3 | Frame Shift Del (DEL) | VAF 34/106 reads (32%) | catalogued as rs35774809; called by mutect2, pindel, varscan2
- FAT1 | c.7144G>A p.D2382N | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374821045, COSV71671869; called by muse, mutect2, varscan2
- FAT2 | c.9490G>A p.A3164T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.624); catalogued as rs200687536, COSV55822526; called by muse, mutect2
- FAT3 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.167); catalogued as rs760614096, COSV53105145; called by muse, mutect2, varscan2
- FBXO28 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 92/243 reads (38%) | catalogued as COSV64800331; called by muse, mutect2, varscan2
- FBXO30 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 82/270 reads (30%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.92); catalogued as rs139321278; called by muse, mutect2, varscan2
- FCF1 | c.101del p.K34Rfs*10 | Frame Shift Del (DEL) | VAF 30/82 reads (37%) | catalogued as rs35842570; called by pindel, varscan2
- FCRL3 | c.814del p.R272Gfs*3 | Frame Shift Del (DEL) | VAF 26/121 reads (21%) | catalogued as rs1288807478; called by mutect2, pindel, varscan2
- FGF7 | c.535del p.T179Rfs*15 | Frame Shift Del (DEL) | VAF 24/96 reads (25%) | catalogued as rs777372807; called by mutect2, varscan2
- FILIP1L | c.1250T>C p.V417A (on ENST00000354552 / NM_182909.3; = p.V177A on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/399 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV100497471; called by muse, mutect2
- FOXO3 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 201/275 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs570814853; called by muse, mutect2, varscan2
- FRA10AC1 | c.76del p.R26Gfs*44 | Frame Shift Del (DEL) | VAF 32/120 reads (27%) | catalogued as rs755202796; called by pindel, varscan2
- FRYL | c.7481C>T p.A2494V | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as rs752057204, COSV99977821; called by muse, mutect2, varscan2
- FSCN3 | c.415del p.R139Dfs*8 | Frame Shift Del (DEL) | VAF 29/91 reads (32%) | catalogued as rs750024016, COSV50002110, COSV99133667; called by mutect2, pindel, varscan2
- FSHR | c.438A>C p.K146N | Missense Mutation (SNP) | VAF 101/255 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0.028); catalogued as COSV58618791, COSV58620376, COSV58630781; called by muse, mutect2, varscan2
- GABRR3 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.446); catalogued as rs781412057, COSV101512282; called by muse, mutect2, varscan2
- GAN | c.652A>G p.M218V | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs1162490245, COSV101633988, COSV73720761; called by muse, mutect2, varscan2
- GARNL3 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767895668; called by muse, mutect2, varscan2
- GFPT2 | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.659); catalogued as rs766235324; called by muse, mutect2, varscan2
- GMEB2 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs375391124; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 44/106 reads (42%) | catalogued as rs370114090; called by mutect2, varscan2
- GPR142 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs772556540, COSV59519366; called by muse, varscan2
- GPR45 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs533753702, COSV99306999; called by muse, mutect2, varscan2
- GRAMD1A | c.1360G>A p.G454S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as rs759830313; called by muse, mutect2, varscan2
- GRIA1 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.496); catalogued as COSV53616156; called by muse, mutect2, varscan2
- GRIK2 | c.2617C>T p.R873C | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs1049934499, COSV59753336; called by muse, mutect2, varscan2
- GRIN2A | c.3476G>A p.R1159H | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs534440095, COSV58020882; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRM5 | c.2500C>T p.R834C | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1471625539, COSV59597532; called by muse, mutect2, varscan2
- GTF2IRD2 | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1422871321; called by muse, mutect2, varscan2
- GUCY1B1 | c.790A>T p.S264C | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs765293059, COSV52374695; called by muse, mutect2, varscan2
- GUF1 | c.1927A>G p.K643E | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs545503516, COSV54945907; called by muse, mutect2, varscan2
- HAL | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs1467184691, COSV99701708; called by muse, mutect2, varscan2
- HEATR5A | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.84); catalogued as COSV66340336; called by muse, mutect2, varscan2
- HIGD1B | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as rs751484914; called by muse, mutect2, varscan2
- HOOK3 | c.236T>A p.I79N | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1395494478, COSV56883424; called by muse, mutect2, varscan2
- HOXD8 | c.676A>G p.R226G | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57485379; called by muse, mutect2
- HSP90B1 | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 81/225 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.233); catalogued as rs373656293; called by muse, mutect2, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | catalogued as rs748579647; called by mutect2, varscan2
- HYDIN | c.14886C>T p.T4962= | Splice Region (SNP) | VAF 13/50 reads (26%) | catalogued as rs747200458; called by muse, mutect2, varscan2
- ICE1 | c.3361G>A p.E1121K | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs752071785, COSV56823531; called by muse, mutect2, varscan2
- IFT74 | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV66286847; called by muse, mutect2, varscan2
- IGFBP1 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51874611, COSV51874856; called by muse, mutect2, varscan2
- IGHV3-23 | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 143/693 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.282); catalogued as rs560385646; called by muse, mutect2, varscan2
- IKBKB | c.1673del p.G558Efs*6 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs1563361838; called by mutect2, varscan2
- IL22RA2 | c.575dup p.N192Kfs*9 | Frame Shift Ins (INS) | VAF 74/274 reads (27%) | catalogued as rs756450081; called by mutect2, varscan2
- IMMT | c.2155C>T p.R719* | Nonsense Mutation (SNP) | VAF 51/144 reads (35%) | catalogued as rs1369239267; called by muse, mutect2, varscan2
- IMPG2 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 89/256 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs756818979, COSV51982261; called by muse, mutect2, varscan2
- INPP5K | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1457203628, COSV57440558; called by muse, mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 72/439 reads (16%) | catalogued as rs1561359523; called by mutect2, varscan2
- IQSEC2 | c.1265G>A p.R422Q (on ENST00000642864 / NM_001111125.3; = p.R217Q on NM_015075.2) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated, low confidence (0.6); PolyPhen possibly damaging (0.905); catalogued as rs782441771, COSV64725162; called by mutect2, varscan2
- IRX5 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58059346; called by muse, mutect2, varscan2
- ITGAE | c.3209C>T p.A1070V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs569409983; called by muse, mutect2, varscan2
- ITPR2 | c.5509dup p.R1837Kfs*4 | Frame Shift Ins (INS) | VAF 50/201 reads (25%) | catalogued as rs1565554999; called by mutect2, varscan2
- KANSL2 | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 91/429 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as rs753092236, COSV63479625; called by muse, mutect2, varscan2
- KCNA6 | c.1522C>T p.R508W | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.673); catalogued as rs763082590, COSV104383208; called by muse, mutect2, varscan2
- KCNAB3 | c.758G>A p.C253Y | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759957113; called by muse, mutect2, varscan2
- KCND1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.904); catalogued as rs139444308, COSV54415571; called by muse, mutect2
- KCNH1 | c.2167C>T p.R723* (on ENST00000271751 / NM_172362.3; = p.R696* on NM_002238.4) | Nonsense Mutation (SNP) | VAF 14/26 reads (54%) | catalogued as rs777413393; called by muse, mutect2, varscan2
- KCNK3 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57192094, COSV57192975; called by muse, mutect2, varscan2
- KCNQ3 | c.2139del p.F713Lfs*6 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs1554621412; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- KDR | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1357848255, COSV55763359; called by muse, mutect2, varscan2
- KIAA2026 | c.5686C>T p.R1896W | Missense Mutation (SNP) | VAF 129/349 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs376802526; called by muse, mutect2, varscan2
- KIF20A | c.1862T>C p.M621T | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV67509756; called by muse, mutect2, varscan2
- KIF21B | c.3601C>T p.R1201W | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs796052152, CM156412; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLK4 | c.627del p.L211* | Frame Shift Del (DEL) | VAF 49/164 reads (30%) | catalogued as rs1410607661; called by mutect2, pindel, varscan2
- KLK4 | c.474C>T p.N158= | Splice Region (SNP) | VAF 28/87 reads (32%) | catalogued as rs745811664, COSV60676094; called by muse, mutect2, varscan2
- KLK9 | c.617del p.G206Afs*65 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as COSV51594097; called by mutect2, varscan2
- KMT2D | c.2546C>T p.S849L | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs370492566, COSV56435429; ClinVar: likely benign / not provided; called by muse, varscan2
- KRTAP10-8 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 84/236 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as rs782578741, COSV58166285; called by muse, mutect2, varscan2
- KSR2 | c.2806C>T p.R936C | Missense Mutation (SNP) | VAF 85/163 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751213911; called by muse, mutect2, varscan2
- KSR2 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100348492; called by muse, mutect2, varscan2
- KTN1 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 104/309 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.11); catalogued as rs748916844; called by muse, mutect2, varscan2
- LAIR1 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs758156418; called by muse, mutect2
- LAMC2 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs926921361; called by muse, mutect2, varscan2
- LARP7 | c.*9del | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs746633076; called by mutect2, varscan2
- LDB3 | c.2023C>A p.P675T | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53940830; called by muse, mutect2, varscan2
- LHX9 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.809); catalogued as COSV61331256; called by muse, mutect2, varscan2
- LMO7 | c.766C>T p.R256C (on ENST00000357063; = p.R271C on NM_005358.5) | Missense Mutation (SNP) | VAF 104/267 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs775510856, COSV58535547; called by muse, mutect2, varscan2
- LMO7 | c.3322C>T p.R1108C (on ENST00000357063; = p.R789C on NM_005358.5) | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369234596, COSV58530118; called by muse, mutect2, varscan2
- LRP1 | c.2689T>C p.S897P | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.575); catalogued as COSV99676473; called by muse, mutect2, varscan2
- LRP2 | c.8407G>A p.V2803I | Missense Mutation (SNP) | VAF 195/330 reads (59%) | SIFT tolerated (0.92); PolyPhen benign (0.014); catalogued as rs765191668; called by muse, mutect2, varscan2
- LRRC55 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1227734456, COSV101546745; called by muse, varscan2
- LRRCC1 | c.1591dup p.M531Nfs*28 | Frame Shift Ins (INS) | VAF 130/407 reads (32%) | catalogued as rs764658669; called by mutect2, pindel, varscan2
- LRRTM4 | c.980A>C p.K327T | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.663); catalogued as COSV69143187; called by muse, mutect2, varscan2
- LTBP2 | c.5194C>A p.L1732I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV56212017; called by muse, mutect2, varscan2
- LUZP4 | c.404A>C p.N135T | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV64218827; called by muse, mutect2, varscan2
- LY6G6C | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 27/63 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as rs750838682, COSV65404314; called by muse, mutect2, varscan2
- MACF1 | c.20954G>A p.R6985Q (on ENST00000372915; = p.R5030Q on NM_012090.5) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | catalogued as rs758006304; called by muse, mutect2, varscan2
- MAGED2 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.681); catalogued as COSV54497540, COSV54498584; called by muse, mutect2, varscan2
- MAML1 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs201881355; called by muse, mutect2, varscan2
- MAP3K4 | c.479del p.N160Mfs*8 | Frame Shift Del (DEL) | VAF 56/186 reads (30%) | catalogued as COSV62334603; called by mutect2, varscan2
- MAP3K9 | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs572761925, COSV67121026; called by muse, mutect2, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 49/170 reads (29%) | catalogued as rs1215313075; called by mutect2, pindel, varscan2
- MARF1 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60022935; called by muse, mutect2, varscan2
- MARF1 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 56/164 reads (34%) | catalogued as COSV60022943; called by muse, mutect2, varscan2
- MARS1 | c.212del p.L71Cfs*33 | Frame Shift Del (DEL) | VAF 42/71 reads (59%) | catalogued as rs751080704; called by mutect2, varscan2
- MARVELD3 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs1044100786; called by muse, mutect2, varscan2
- MBTD1 | c.1652A>G p.Q551R | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV64503293; called by muse, mutect2, varscan2
- MCM10 | c.1577C>T p.P526L (on ENST00000484800 / NM_182751.3; = p.P525L on NM_018518.5) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758103796, COSV66334179; called by muse, mutect2, varscan2
- MCM10 | c.2102del p.N701Tfs*35 (on ENST00000484800 / NM_182751.3; = p.N700Tfs*35 on NM_018518.5) | Frame Shift Del (DEL) | VAF 43/113 reads (38%) | catalogued as rs772561920; called by mutect2, pindel, varscan2
- MCM10 | c.2155del p.R719Gfs*17 (on ENST00000484800 / NM_182751.3; = p.R718Gfs*17 on NM_018518.5) | Frame Shift Del (DEL) | VAF 31/107 reads (29%) | catalogued as rs1310004144; called by mutect2, pindel, varscan2
- MECOM | c.1839del p.G614Efs*30 (on ENST00000468789 / NM_001105078.4; = p.G802Efs*30 on NM_004991.4) | Frame Shift Del (DEL) | VAF 31/85 reads (36%) | catalogued as rs773080349; called by mutect2, varscan2
- MELK | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs868229295; called by muse, varscan2
- METTL16 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 99/2116 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as COSV99563696, COSV99563839; called by muse, mutect2
- METTL6 | c.145del p.Y49Tfs*22 | Frame Shift Del (DEL) | VAF 50/215 reads (23%) | catalogued as rs1227964106; called by mutect2, pindel, varscan2
- MEX3A | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs1464692981; called by muse, mutect2
- MGP | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 143/505 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV57454336; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 42/128 reads (33%) | catalogued as rs755830405; called by mutect2, varscan2
- MPRIP | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 323/352 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59051052; called by muse, mutect2, varscan2
- MRAP2 | c.186dup p.V63Cfs*40 | Frame Shift Ins (INS) | VAF 52/166 reads (31%) | catalogued as rs758625941; called by mutect2, pindel, varscan2
- MRGPRX1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.506); catalogued as rs767184906, COSV57106940; called by muse, mutect2, varscan2
- MSH5 | c.1891A>G p.I631V | Missense Mutation (SNP) | VAF 42/62 reads (68%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as COSV65173126; called by muse, mutect2, varscan2
- MSH6 | c.3070C>T p.R1024W | Missense Mutation (SNP) | VAF 96/266 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs370505117; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MXRA5 | c.844T>C p.S282P | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs147525665; called by muse, mutect2, varscan2
- MYCBP2 | c.7727T>C p.I2576T (on ENST00000357337; = p.I2614T on NM_015057.5) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs1178930934, COSV62017340; called by muse, mutect2, varscan2
- MYH1 | c.3848G>A p.R1283H | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs749373460, COSV56847132; called by muse, mutect2, varscan2
- MYH10 | c.2591T>C p.V864A | Missense Mutation (SNP) | VAF 80/256 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1243767553; called by muse, varscan2
- MYO10 | c.3666dup p.G1223Rfs*28 | Frame Shift Ins (INS) | VAF 12/68 reads (18%) | catalogued as COSV57020181; called by pindel, varscan2
- MYO16 | c.1514A>C p.E505A | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs758217754; called by muse, mutect2, varscan2
- NAA80 | c.134C>A p.P45H (on ENST00000417393 / NM_001200018.2; = p.P67H on NM_012191.4) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); catalogued as COSV99807796; called by muse, mutect2
- NAALADL1 | c.1022T>C p.L341P | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.615); catalogued as rs1427280757; called by muse, mutect2, varscan2
- NAP1L3 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1163788167, COSV59073966; called by muse, varscan2
- NCAM2 | c.1522T>C p.S508P | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV99523375; called by muse, mutect2, varscan2
- NCAPD3 | c.2725del p.Q909Rfs*10 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | catalogued as rs770284236; called by mutect2, pindel, varscan2
- NCOA4 | c.1684C>T p.R562* | Nonsense Mutation (SNP) | VAF 34/136 reads (25%) | catalogued as rs782538857; called by muse, mutect2, varscan2
- NCOA6 | c.3551C>T p.P1184L | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.276); catalogued as COSV62862173; called by muse, mutect2, varscan2
- NDUFA10 | c.604del p.H202Tfs*3 | Frame Shift Del (DEL) | VAF 28/108 reads (26%) | catalogued as rs746019378; ClinVar: uncertain significance; called by mutect2, pindel
- NEB | c.14840C>T p.S4947L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as rs780754459, COSV51269633; called by muse, mutect2, varscan2
- NECAP2 | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778687400; called by muse, mutect2, varscan2
- NEFM | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV55332285; called by muse, mutect2, varscan2
- NEUROD6 | c.248del p.K83Rfs*35 | Frame Shift Del (DEL) | VAF 83/226 reads (37%) | catalogued as rs752284115; called by mutect2, varscan2
- NEXN | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1329703763; called by muse, mutect2, varscan2
- NF1 | c.3455T>C p.L1152S | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62201851; called by muse, mutect2, varscan2
- NIPBL | c.3334_3336del p.D1112del | In Frame Del (DEL) | VAF 23/69 reads (33%) | catalogued as rs1196574237; called by pindel, varscan2
- NIPBL | c.4907G>A p.R1636H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.851); catalogued as COSV56948222; called by muse, mutect2, varscan2
- NIPBL | c.7439_7440del p.R2480Kfs*5 | Frame Shift Del (DEL) | VAF 48/179 reads (27%) | catalogued as rs587784043; called by pindel, varscan2
- NLGN4X | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as rs770601703, COSV52041833; called by muse, mutect2, varscan2
- NLRC4 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 23/73 reads (32%) | catalogued as rs1375308560, COSV61592417; called by muse, mutect2, varscan2
- NME9 | c.742G>A p.V248I (on ENST00000333911 / NM_001349024.2; = p.V187I on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs763521362, COSV58616800; called by muse, mutect2, varscan2
- NOS1 | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs774868068, COSV57622182; called by muse, mutect2
- NPPB | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750160819, COSV100916075; called by muse, mutect2, varscan2
- NR1H3 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs778600458; called by muse, mutect2, varscan2
- NR4A3 | c.5C>A p.P2H | Missense Mutation (SNP) | VAF 133/191 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58244051, COSV58244536; called by muse, mutect2, varscan2
- NRAP | c.3109C>T p.R1037* (on ENST00000359988 / NM_001322945.2; = p.R1002* on NM_006175.4) | Nonsense Mutation (SNP) | VAF 27/91 reads (30%) | catalogued as rs868110215, COSV63489489; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 34/107 reads (32%) | catalogued as rs776154715; called by mutect2, varscan2
- NXF1 | c.1463G>A p.S488N | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV53674031; called by muse, mutect2, varscan2
- OCA2 | c.1841del p.K614Sfs*14 | Frame Shift Del (DEL) | VAF 41/147 reads (28%) | catalogued as CD000269; called by mutect2, pindel, varscan2
- ODAPH | c.283T>C p.C95R | Missense Mutation (SNP) | VAF 86/242 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1560562937; called by muse, varscan2
- OR10H5 | c.541G>A p.V181M | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.089); catalogued as rs776618344, COSV58277743, COSV58277919; called by muse, mutect2, varscan2
- OR10P1 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 70/307 reads (23%) | catalogued as rs1252391226; called by muse, mutect2, varscan2
- OR13F1 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 94/247 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs766574405, COSV58251471; called by muse, mutect2, varscan2
- OR1A2 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 216/678 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs747734786, COSV67936366; called by muse, mutect2, varscan2
- OR2T6 | c.908G>T p.R303I | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs757906212; called by muse, mutect2, varscan2
- OR4C12 | c.92T>G p.V31G | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as COSV58859853; called by muse, mutect2, varscan2
- OR4C15 | c.346T>G p.L116V (on ENST00000314644; = p.L62V on NM_001001920.2) | Missense Mutation (SNP) | VAF 149/392 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58952394, COSV58952408, COSV58954071; called by muse, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | catalogued as rs755413956; called by mutect2, varscan2
- OR5C1 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs112725288, COSV65456313; called by muse, mutect2, varscan2
- OR5R1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771782696, COSV56571910; called by muse, mutect2, varscan2
- OR6C4 | c.303del p.F101Lfs*31 | Frame Shift Del (DEL) | VAF 184/453 reads (41%) | catalogued as COSV67793317; called by mutect2, pindel, varscan2
- OR6N1 | c.151C>A p.L51M | Missense Mutation (SNP) | VAF 127/330 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.051); catalogued as COSV58648698; called by muse, mutect2, varscan2
- OR8G1 | c.803T>C p.M268T | Missense Mutation (SNP) | VAF 17/346 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); catalogued as COSV58379903; called by muse, mutect2
- ORC1 | c.1822C>T p.R608* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as rs1368174201, COSV65363715; called by muse, mutect2, varscan2
- OSBP2 | c.835G>A p.V279M | Missense Mutation (SNP) | VAF 137/141 reads (97%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753497112, COSV60247787; called by muse, mutect2, varscan2
- PANK1 | c.754T>G p.Y252D (on ENST00000307534 / NM_148977.2; = p.Y27D on NM_138316.4) | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56807919; called by muse, mutect2, varscan2
- PAPOLG | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.03); catalogued as rs776380211, COSV99475003; called by muse, mutect2
- PAPSS2 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1305827667, COSV100753647, COSV63263293; called by muse, mutect2, varscan2
- PARP3 | c.440C>A p.P147Q | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.263); catalogued as COSV51754136; called by muse, mutect2, varscan2
- PCDHB2 | c.223del p.M75Cfs*14 | Frame Shift Del (DEL) | VAF 22/77 reads (29%) | catalogued as rs782086614; called by mutect2, varscan2
- PCDHB4 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV52023220; called by muse, mutect2, varscan2
- PCDHB4 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.127); catalogued as rs782259034, COSV52023078; called by muse, mutect2, varscan2
- PCDHB5 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); catalogued as COSV50650492; called by muse, mutect2, varscan2
- PCDHB7 | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1554280062; called by muse, mutect2, varscan2
- PCDHGA8 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV53938644; called by muse, mutect2
- PCDHGA8 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.03); catalogued as COSV53938654; called by muse, mutect2, varscan2
- PCNT | c.4855A>G p.T1619A | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs747256738; called by muse, varscan2
- PDE1B | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs755706489, COSV54490558; called by muse, mutect2, varscan2
- PDS5B | c.3592del p.S1198Vfs*10 | Frame Shift Del (DEL) | VAF 34/138 reads (25%) | catalogued as rs755801132, COSV59734300; called by mutect2, pindel, varscan2
- PDZD2 | c.3209C>A p.P1070H | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); catalogued as COSV56877382; called by muse, mutect2
- PEG3 | c.1673G>A p.G558D | Missense Mutation (SNP) | VAF 73/230 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV55628911; called by muse, mutect2, varscan2
- PGBD4 | c.1751del p.N584Ifs*21 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | catalogued as rs770560794; called by mutect2, varscan2
- PHACTR1 | c.759del p.P254Qfs*59 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs749326031; called by mutect2, pindel
- PHLPP1 | c.3638G>A p.R1213Q | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1269322420; called by muse, mutect2, varscan2
- PIK3R5 | c.418T>G p.S140A | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV52653368; called by muse, mutect2, varscan2
- PIWIL3 | c.2395_2397del p.F799del | In Frame Del (DEL) | VAF 35/118 reads (30%) | catalogued as rs778583073; called by mutect2, pindel, varscan2
- PKD1L1 | c.3524C>T p.S1175L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs758983757; called by muse, mutect2, varscan2
- PKD2 | c.1090A>G p.T364A | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV52938127; called by muse, mutect2, varscan2
- PLA2R1 | c.3519G>A p.W1173* | Nonsense Mutation (SNP) | VAF 46/161 reads (29%) | catalogued as COSV51784283, COSV51785705; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs745860467; called by mutect2, varscan2
- PLCB4 | c.2413G>T p.G805* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as rs199684222, COSV53803224; called by muse, mutect2, varscan2
- PLCH1 | c.155G>A p.R52Q (on ENST00000340059 / NM_001130960.2; = p.R64Q on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs370205187; called by muse, mutect2, varscan2
- PLXNA4 | c.2892del p.M966Cfs*7 | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | catalogued as COSV100328104; called by mutect2, pindel, varscan2
- PLXNB1 | c.5995G>A p.V1999M | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1394169885, COSV56490652; called by muse, mutect2
- POLR1B | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs376500705; called by muse, mutect2, varscan2
- POLR1E | c.591G>T p.M197I (on ENST00000377792 / NM_001282766.1; = p.M135I on NM_022490.4) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.082); catalogued as COSV100905423; called by muse, mutect2, varscan2
- POLR3B | c.833dup p.T279Hfs*46 | Frame Shift Ins (INS) | VAF 50/230 reads (22%) | catalogued as rs1261509815; called by mutect2, pindel, varscan2
- POTED | c.977A>G p.E326G | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs1229304342; called by mutect2, varscan2
- POU4F2 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.31); catalogued as rs760611375, COSV55585072; called by muse, mutect2, varscan2
- PPFIBP2 | c.2405A>G p.Y802C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1486730972; called by muse, mutect2
- PPM1D | c.1535del p.N512Ifs*2 | Frame Shift Del (DEL) | VAF 25/185 reads (14%) | catalogued as rs763475304; called by mutect2, pindel, varscan2
- PPP2R3C | c.67del p.S23Vfs*5 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs758484975; called by mutect2, varscan2
- PRDM1 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.65); catalogued as rs778818420, COSV64844270; called by muse, mutect2, varscan2
- PRDM9 | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as rs1425057806, COSV57002819, COSV57012319; called by muse, mutect2, varscan2
- PREX2 | c.1693del p.S565Rfs*10 | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | catalogued as rs764112302; called by mutect2, varscan2
- PRMT8 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54218880; called by muse, mutect2, varscan2
- PROK2 | c.349C>T p.R117W (on ENST00000295619 / NM_001126128.2; = p.R96W on NM_021935.4) | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs750885767, COSV55208730; called by muse, mutect2, varscan2
- PTGFR | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747135810; called by muse, mutect2, varscan2
- PTPN13 | c.7382A>G p.Y2461C (on ENST00000411767 / NM_080683.3; = p.Y2442C on NM_006264.3) | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746257466; called by muse, mutect2, varscan2
- PTPN21 | c.2545del p.I849Lfs*9 | Frame Shift Del (DEL) | VAF 26/62 reads (42%) | catalogued as rs778292578; called by mutect2, varscan2
- PTPRZ1 | c.2869A>G p.T957A | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as COSV66435720; called by mutect2, varscan2
- PUM3 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 94/312 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as rs1365974206; called by muse, mutect2, varscan2
- PYGL | c.2028del p.T677Qfs*4 | Frame Shift Del (DEL) | VAF 55/199 reads (28%) | catalogued as rs772998983; called by mutect2, pindel, varscan2
- QRSL1 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.442); catalogued as rs776695628, COSV64687345; called by muse, mutect2, varscan2
- R3HDM1 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1324038149, COSV51524140; called by muse, mutect2, varscan2
- RAB11FIP2 | c.943T>A p.F315I | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV100843188; called by muse, mutect2, varscan2
- RAB40AL | c.805A>C p.N269H | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV54434329; called by muse, varscan2
- RABL3 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 89/299 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.58); catalogued as rs59155676; called by muse, mutect2, varscan2
- RARA | c.656C>A p.S219Y | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV54191981; called by muse, mutect2, varscan2
- RBM33 | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.21); catalogued as COSV55296801; called by muse, varscan2
- RBM34 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs761837567, COSV100784015; called by muse, mutect2, varscan2
- RBM34 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as rs752241692; called by muse, mutect2, varscan2
- RBM43 | c.406del p.I136Sfs*4 | Frame Shift Del (DEL) | VAF 54/202 reads (27%) | catalogued as rs142934811, CD1212851; called by mutect2, varscan2
- RBMS1 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV62352801; called by muse, mutect2, varscan2
- RCC2 | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as rs757048358, COSV64905628; called by muse, mutect2, varscan2
- RFC3 | c.244del p.I82Lfs*25 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs753959887; called by mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 12/18 reads (67%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RING1 | c.517del p.E173Kfs*14 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs761874510; called by mutect2, pindel
- RINT1 | c.740del p.P247Lfs*8 | Frame Shift Del (DEL) | VAF 45/206 reads (22%) | catalogued as rs1352349454; called by pindel, varscan2
- RNASET2 | c.108del p.K36Nfs*2 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs1268218510; called by mutect2, pindel, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 156/226 reads (69%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF152 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1419247946; called by muse, mutect2, varscan2
- RNF183 | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 39/50 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781139505, COSV52907550; called by muse, mutect2, varscan2
- RNF216 | c.490G>A p.D164N (on ENST00000425013 / NM_207116.3; = p.D221N on NM_207111.4) | Missense Mutation (SNP) | VAF 406/467 reads (87%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV66290276; called by muse, mutect2, varscan2
- RNF32 | c.199dup p.T67Nfs*17 | Frame Shift Ins (INS) | VAF 39/101 reads (39%) | catalogued as rs771776056; called by mutect2, varscan2
- RNF8 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV57721179; called by muse, mutect2, varscan2
- ROBO2 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1286299008, COSV59894367; called by muse, mutect2, varscan2
- ROCK1 | c.1051+2T>C p.X351_splice | Splice Site (SNP) | VAF 25/99 reads (25%) | catalogued as COSV67695721; called by muse, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 38/55 reads (69%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL6 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as COSV52517049; called by muse, mutect2, varscan2
- RTL8B | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as rs753993756, COSV66954259; called by muse, mutect2, varscan2
- RTTN | c.5744del p.K1915Rfs*9 | Frame Shift Del (DEL) | VAF 73/196 reads (37%) | catalogued as rs756606313; called by mutect2, varscan2
- RUBCN | c.830dup p.V278Sfs*16 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | catalogued as rs745498865; called by mutect2, varscan2
- RXRG | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.94); catalogued as CM071980; called by muse, mutect2, varscan2
- RYR1 | c.5122G>A p.A1708T | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.18); catalogued as rs376833141, COSV100614740; called by muse, mutect2, varscan2
- SAAL1 | c.855A>G p.V285= | Splice Region (SNP) | VAF 64/177 reads (36%) | catalogued as COSV55514896; called by muse, mutect2, varscan2
- SAMD4B | c.1680A>G p.I560M | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV58750428; called by muse, mutect2, varscan2
- SATB1 | c.1942C>T p.R648* | Nonsense Mutation (SNP) | VAF 24/72 reads (33%) | catalogued as COSV58669179; called by muse, mutect2, varscan2
- SBDS | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as CM058308, CM1515418; called by muse, mutect2, varscan2
- SCAPER | c.2613del p.A872Pfs*4 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs757259031; called by mutect2, varscan2
- SEC24C | c.896C>A p.P299H | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.401); catalogued as COSV59541582; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 32/114 reads (28%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SENP7 | c.1635del p.K545Nfs*11 | Frame Shift Del (DEL) | VAF 29/74 reads (39%) | catalogued as rs764980440, COSV58616367; called by mutect2, pindel, varscan2
- SEZ6L | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as rs1336431146; called by muse, mutect2, varscan2
- SFRP1 | c.845C>T p.T282M | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.354); catalogued as rs761465184, COSV55173215; called by muse, mutect2, varscan2
- SHPK | c.1270G>A p.V424M | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs755670371, COSV56648965; called by muse, mutect2, varscan2
- SHPRH | c.3694C>T p.R1232* (on ENST00000275233 / NM_001042683.3; = p.R1236* on NM_173082.3) | Nonsense Mutation (SNP) | VAF 44/101 reads (44%) | catalogued as rs749605640; called by muse, mutect2, varscan2
- SHQ1 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs762002222; called by muse, mutect2, varscan2
- SHROOM4 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as rs371697426, COSV56784797; called by muse, mutect2, varscan2
- SLC12A5 | c.1210G>A p.D404N (on ENST00000454036 / NM_001134771.2; = p.D381N on NM_020708.5) | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs776238585, COSV54792870, COSV54793557; called by muse, mutect2, varscan2
- SLC12A8 | c.1660C>A p.Q554K | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV58863467; called by muse, mutect2, varscan2
- SLC24A1 | c.499A>G p.T167A | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as rs755024080; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 27/61 reads (44%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC44A5 | c.373T>A p.F125I | Missense Mutation (SNP) | VAF 74/251 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV63767300; called by muse, mutect2, varscan2
- SLC5A7 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs961639912, COSV99886827; called by muse, mutect2, varscan2
- SLF2 | c.2539C>T p.P847S | Missense Mutation (SNP) | VAF 92/291 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as rs867292077; called by muse, mutect2, varscan2
- SLTM | c.1474A>G p.S492G | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1429151217; called by muse, mutect2, varscan2
- SMARCA2 | c.3653A>G p.Q1218R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.932); catalogued as COSV61806962; called by muse, mutect2, varscan2
- SMO | c.843G>A p.W281* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV50825106; called by muse, mutect2, varscan2
- SMUG1 | c.434T>C p.F145S | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV54538912; called by muse, mutect2, varscan2
- SNAPC1 | c.200dup p.L67Ffs*21 | Frame Shift Ins (INS) | VAF 16/49 reads (33%) | catalogued as rs753183177; called by mutect2, pindel, varscan2
- SNTA1 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761509610, COSV54129310; called by muse, varscan2
- SNTG2 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1444627239, COSV57975870; called by muse, mutect2, varscan2
- SNTN | c.13A>G p.M5V | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs1405911398; called by muse, mutect2, varscan2
- SORBS2 | c.3130del p.E1044Nfs*65 (on ENST00000284776 / NM_021069.5; = p.E610Nfs*65 on NM_003603.6) | Frame Shift Del (DEL) | VAF 84/278 reads (30%) | catalogued as rs772549791, COSV52996321; called by mutect2, pindel, varscan2
- SOX5 | c.2180A>C p.Q727P | Missense Mutation (SNP) | VAF 86/156 reads (55%) | SIFT tolerated (0.34); PolyPhen benign (0.043); catalogued as COSV58653361; called by muse, mutect2, varscan2
- SP1 | c.558G>T p.Q186H (on ENST00000327443 / NM_138473.3; = p.Q179H on NM_003109.1) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); catalogued as COSV59402698; called by muse, mutect2, varscan2
- SPAG9 | c.1645del p.R549Gfs*28 (on ENST00000262013 / NM_001130528.3; = p.R535Gfs*28 on NM_003971.6) | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs371303534; called by mutect2, varscan2
- SPIN1 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs751098696; called by muse, mutect2, varscan2
- SPTB | c.2555C>T p.T852M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs753867736, COSV67633724; called by muse, mutect2, varscan2
- SRCIN1 | c.3293G>A p.R1098H (on ENST00000621492; = p.R1064H on NM_025248.3) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs868454371; called by muse, mutect2
- SRGAP2 | c.2536C>T p.R846W (on ENST00000624873 / NM_001170637.4; = p.R847W on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs373934616; called by muse, mutect2
- SRPX | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as COSV59437504; called by muse, mutect2, varscan2
- SRSF12 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as rs1221610287, COSV71683619; called by muse, mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 38/98 reads (39%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as rs752994755; called by mutect2, varscan2
- STAT4 | c.610A>C p.S204R | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV61828594, COSV61829529; called by muse, mutect2
- STC1 | c.284G>A p.S95N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as rs1433614409; called by muse, mutect2, varscan2
- STOX2 | c.2717C>A p.T906K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as COSV57851692; called by muse, mutect2, varscan2
- STX7 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); catalogued as rs746429926; called by muse, mutect2, varscan2
- SUPT6H | c.2596C>T p.R866C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as rs561572434, COSV58927045; called by muse, mutect2, varscan2
- SYNE2 | c.8891G>A p.R2964H | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs769752828, COSV59948760; called by muse, mutect2, varscan2
- SYNJ1 | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs745374780; called by muse, mutect2, varscan2
- SYT16 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368814141; called by muse, mutect2, varscan2
- TAF2 | c.1278-3del | Splice Region (DEL) | VAF 11/51 reads (22%) | catalogued as rs751147458; called by mutect2, varscan2
- TAGAP | c.2134C>T p.R712* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV57850500; called by muse, mutect2, varscan2
- TANK | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759803420, COSV52045942; called by muse, mutect2, varscan2
- TAOK2 | c.353-2A>G p.X118_splice | Splice Site (SNP) | VAF 38/114 reads (33%) | catalogued as COSV54235386; called by muse, mutect2, varscan2
- TAOK3 | c.1741C>T p.R581W | Missense Mutation (SNP) | VAF 89/172 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs368702140; called by muse, mutect2, varscan2
- TBC1D1 | c.928del p.I310* | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | catalogued as rs760298745; called by mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 40/112 reads (36%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBC1D31 | c.1893del p.H632Tfs*8 | Frame Shift Del (DEL) | VAF 31/97 reads (32%) | catalogued as rs768246273; called by mutect2, varscan2
- TBC1D9 | c.1096C>T p.L366F | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV71307374; called by muse, mutect2, varscan2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 47/136 reads (35%) | catalogued as rs745872748; called by mutect2, varscan2
- TCOF1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as rs371609378; called by muse, mutect2, varscan2
- TDRD5 | c.1636A>G p.I546V | Missense Mutation (SNP) | VAF 177/541 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as rs1229046181; called by muse, mutect2, varscan2
- TECTA | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1364447010; called by muse, mutect2, varscan2
- TECTA | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as rs751352958, COSV50687793; called by muse, mutect2, varscan2
- TEP1 | c.1574C>A p.A525D | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52990757; called by muse, mutect2
- TFDP2 | c.797C>T p.P266L (on ENST00000489671 / NM_001178139.2; = p.P206L on NM_006286.5) | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1364114367, COSV57707413; called by muse, mutect2, varscan2
- TGFBR3 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs767943888; called by muse, mutect2, varscan2
- THOC2 | c.2262C>G p.I754M | Missense Mutation (SNP) | VAF 67/242 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV99833866; called by muse, mutect2, varscan2
- TJP2 | c.2195C>A p.P732H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55268683; called by muse, mutect2, varscan2
- TLE1 | c.1748G>A p.S583N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64720720; called by muse, mutect2, varscan2
- TLN2 | c.6272C>T p.A2091V | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs748536008, COSV100168601; called by muse, mutect2, varscan2
- TMBIM4 | c.520del p.Y174Ifs*4 | Frame Shift Del (DEL) | VAF 27/78 reads (35%) | catalogued as rs754390908; called by mutect2, varscan2
- TMEFF1 | c.1069A>C p.K357Q | Missense Mutation (SNP) | VAF 84/242 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs139218600; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 56/133 reads (42%) | catalogued as rs749773249; called by mutect2, varscan2
- TMEM9B | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs764636398, COSV100483575; called by muse, mutect2, varscan2
- TMOD4 | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV54860449; called by muse, mutect2, varscan2
- TMTC1 | c.1705A>G p.T569A (on ENST00000539277 / NM_001193451.2; = p.T461A on NM_175861.3) | Missense Mutation (SNP) | VAF 80/403 reads (20%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV55483616; called by muse, mutect2, varscan2
- TNFRSF9 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs777956091; called by muse, mutect2, varscan2
- TNMD | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs377645140, COSV65977721; called by muse, mutect2, varscan2
- TNN | c.2543G>A p.S848N | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs1383490442, COSV53436435; called by muse, mutect2, varscan2
- TRAPPC9 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs918171653; called by muse, mutect2, varscan2
- TRAPPC9 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757282308, COSV66908463; called by muse, mutect2, varscan2
- TRIM3 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV61984853; called by muse, mutect2, varscan2
- TRPM1 | c.770del p.G257Afs*21 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as rs760418372, COSV99855452; called by mutect2, pindel, varscan2
- TRPM3 | c.4357G>T p.A1453S (on ENST00000357533 / NM_001366142.2; = p.A1308S on NM_020952.6) | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV62585093; called by muse, mutect2, varscan2
- TRPS1 | c.2084G>A p.R695H (on ENST00000220888 / NM_001330599.2; = p.R708H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1322890657, COSV55234192; called by muse, mutect2, varscan2
- TRRAP | c.3646C>T p.R1216W | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.409); catalogued as rs757085445, COSV62838590; called by mutect2, varscan2
- TRRAP | c.5249G>A p.R1750H (on ENST00000359863 / NM_001244580.1; = p.R1732H on NM_003496.3) | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100722379; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 32/92 reads (35%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.89501_89503del p.E29834del (on ENST00000591111; = p.E22410del on NM_003319.4) | In Frame Del (DEL) | VAF 75/215 reads (35%) | catalogued as rs1430587207; called by mutect2, pindel, varscan2
- TTN | c.41485C>T p.R13829C (on ENST00000591111; = p.R6405C on NM_003319.4) | Missense Mutation (SNP) | VAF 53/139 reads (38%) | PolyPhen probably damaging (0.998); catalogued as rs373502448, COSV60336952; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.35591C>T p.P11864L (on ENST00000591111; = p.P4440L on NM_003319.4) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | PolyPhen probably damaging (0.998); catalogued as rs371714559, COSV100636116; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA1C | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV56510211; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 62/86 reads (72%) | catalogued as rs760251146; called by mutect2, varscan2
- UBA1 | c.2309A>G p.N770S | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1178361928; ClinVar: likely benign; called by muse, mutect2, varscan2
- UBE2J2 | c.316A>G p.N106D | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59572206; called by muse, mutect2, varscan2
- UGDH | c.214del p.S72Lfs*18 | Frame Shift Del (DEL) | VAF 56/130 reads (43%) | catalogued as rs765734647, COSV57097233; called by mutect2, varscan2
- UHRF1BP1 | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as rs1325079430; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs182322349, COSV54443971; called by muse, varscan2
- UNC5CL | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55109022; called by muse, mutect2, varscan2
- UQCRC1 | c.537G>A p.M179I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV52551563, COSV52552101; called by muse, mutect2, varscan2
- UROC1 | c.920del p.K307Rfs*77 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs754361807; called by mutect2, varscan2
- USF3 | c.439del p.I147Lfs*22 | Frame Shift Del (DEL) | VAF 88/258 reads (34%) | catalogued as rs747493460; called by mutect2, varscan2
- USO1 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773378481; called by muse, mutect2, varscan2
- USP11 | c.2761G>A p.A921T (on ENST00000218348; = p.A878T on NM_001371072.1) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54473994; called by muse, mutect2, varscan2
- USP29 | c.212A>G p.H71R | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.343); catalogued as rs1349815549; called by muse, mutect2, varscan2
- USP43 | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 23/73 reads (32%) | catalogued as COSV53299734; called by muse, mutect2, varscan2
- UST | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 238/311 reads (77%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.245); catalogued as rs1243550496; called by muse, mutect2, varscan2
- UVRAG | c.709del p.S237Vfs*6 | Frame Shift Del (DEL) | VAF 30/102 reads (29%) | catalogued as rs762976381; called by mutect2, varscan2
- VAPA | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759019820; called by muse, mutect2, varscan2
- VCL | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1489339580, COSV53011478; called by muse, mutect2, varscan2
- VEPH1 | c.1661del p.N554Tfs*5 | Frame Shift Del (DEL) | VAF 64/218 reads (29%) | catalogued as rs756863093; called by mutect2, varscan2
- VEPH1 | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 50/140 reads (36%) | catalogued as rs1444724633; called by muse, mutect2, varscan2
- VPS13A | c.1115del p.K372Sfs*2 | Frame Shift Del (DEL) | VAF 100/287 reads (35%) | catalogued as rs770350986; called by mutect2, varscan2
- VRK2 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs765840317, COSV60874774, COSV60876163; called by muse, mutect2, varscan2
- WDR47 | c.241del p.R81Gfs*7 | Frame Shift Del (DEL) | VAF 52/140 reads (37%) | catalogued as rs1557951659, COSV63058584; called by mutect2, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs746919573; called by mutect2, varscan2
- WDR59 | c.479del p.N160Mfs*28 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs762980273; called by mutect2, varscan2
- WFDC10B | c.50_52dup p.L17dup | In Frame Ins (INS) | VAF 12/31 reads (39%) | catalogued as rs1384955917; called by mutect2, varscan2
- WLS | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs764615459, COSV52040347; called by muse, mutect2, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 9/19 reads (47%) | catalogued as rs762079039; called by mutect2, varscan2
- WNT16 | c.500del p.G167Afs*17 (on ENST00000222462 / NM_057168.2; = p.G157Afs*17 on NM_016087.2) | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs771899177; called by mutect2, pindel
- WNT5A | c.1021G>T p.G341C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99224758; called by muse, mutect2, varscan2
- WWC1 | c.2615C>T p.T872I | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1195930830; called by muse, mutect2, varscan2
- XAGE3 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 101/722 reads (14%) | catalogued as rs781784978; called by muse, mutect2, varscan2
- XDH | c.2827C>T p.R943W | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759966525, COSV65150656; called by muse, mutect2, varscan2
- XIRP2 | c.9418G>T p.A3140S (on ENST00000628543; = p.A3315S on NM_152381.6) | Missense Mutation (SNP) | VAF 99/236 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV54688884; called by muse, mutect2, varscan2
- XKR4 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 25/84 reads (30%) | catalogued as rs867767654, COSV59340929; called by muse, mutect2, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 14/105 reads (13%) | catalogued as rs762052135; called by mutect2, varscan2
- YLPM1 | c.5071_5072del p.D1691Sfs*2 | Frame Shift Del (DEL) | VAF 51/194 reads (26%) | catalogued as rs764194709; called by pindel, varscan2
- ZADH2 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779172968, COSV59268171; called by muse, mutect2, varscan2
- ZAN | c.2051T>C p.I684T | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.537); catalogued as rs1456950122; called by muse, mutect2, varscan2
- ZBED9 | c.2425G>A p.V809M | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs1381489347, COSV71729781; called by muse, mutect2, varscan2
- ZBTB20 | c.571C>T p.R191C (on ENST00000474710 / NM_001164342.2; = p.R118C on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61871055; called by muse, mutect2, varscan2
- ZBTB6 | c.431A>G p.Q144R | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV65409834; called by muse, mutect2, varscan2
- ZCCHC14 | c.1498G>A p.A500T (on ENST00000268616; = p.A637T on NM_015144.3) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as rs746458521, COSV51886936; called by muse, mutect2, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 34/95 reads (36%) | catalogued as rs745875253; called by mutect2, varscan2
- ZFHX4 | c.8504C>T p.P2835L | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.09); catalogued as rs764416836, COSV50499819; called by muse, mutect2, varscan2
- ZFP37 | c.482del p.N161Ifs*24 | Frame Shift Del (DEL) | VAF 60/190 reads (32%) | catalogued as rs563751025; called by mutect2, varscan2
- ZFR | c.1074del p.E359Kfs*4 | Frame Shift Del (DEL) | VAF 118/321 reads (37%) | catalogued as rs751974853; called by mutect2, varscan2
- ZMYND8 | c.2249C>T p.T750M (on ENST00000311275 / NM_001363741.2; = p.T770M on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.411); catalogued as rs1006081568; called by muse, mutect2, varscan2
- ZNF106 | c.4193C>T p.T1398I | Missense Mutation (SNP) | VAF 99/314 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs147387765; called by muse, mutect2, varscan2
- ZNF106 | c.3135del p.E1046Nfs*9 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as rs1306306437; called by mutect2, pindel, varscan2
- ZNF337 | c.1567C>T p.R523* | Nonsense Mutation (SNP) | VAF 98/277 reads (35%) | catalogued as rs755897803, COSV53321226; called by muse, mutect2, varscan2
- ZNF37A | c.553A>T p.M185L | Missense Mutation (SNP) | VAF 99/271 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs747587314, COSV61073485; called by muse, mutect2, varscan2
- ZNF416 | c.718del p.R240Gfs*46 | Frame Shift Del (DEL) | VAF 60/213 reads (28%) | catalogued as COSV52185917; called by mutect2, pindel, varscan2
- ZNF425 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100955618; called by muse, mutect2, varscan2
- ZNF45 | c.1326del p.K442Nfs*98 | Frame Shift Del (DEL) | VAF 61/219 reads (28%) | catalogued as COSV54193149; called by mutect2, pindel, varscan2
- ZNF454 | c.611del p.N204Mfs*52 | Frame Shift Del (DEL) | VAF 46/163 reads (28%) | catalogued as rs752005964; called by mutect2, pindel, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 40/134 reads (30%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF556 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as rs775935402; called by muse, mutect2, varscan2
- ZNF613 | c.1060C>T p.R354C (on ENST00000293471 / NM_001031721.4; = p.R318C on NM_024840.4) | Missense Mutation (SNP) | VAF 95/271 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.046); catalogued as rs187106625; called by muse, mutect2, varscan2
- ZNF654 | c.3247G>A p.V1083M | Missense Mutation (SNP) | VAF 389/524 reads (74%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs374266455, COSV58805685; called by muse, mutect2, varscan2
- ZNF668 | c.1708C>T p.R570C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs763330703, COSV56213868; called by muse, mutect2
- ZNF701 | c.894del p.K298Nfs*4 (on ENST00000301093; = p.K232Nfs*4 on NM_018260.3) | Frame Shift Del (DEL) | VAF 34/171 reads (20%) | catalogued as rs762217868; called by mutect2, pindel, varscan2
- ZNF836 | c.2015G>A p.G672D | Missense Mutation (SNP) | VAF 109/264 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs746267089, COSV59082870; called by muse, mutect2, varscan2
- ABCA13 | c.5121T>A p.N1707K | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ABCA5 | c.2053G>A p.V685M | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCB5 | c.875G>C p.G292A | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCG2 | c.1930G>A p.A644T | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ACACA | c.5914C>T p.R1972* | Nonsense Mutation (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- ACAT1 | c.167del p.L56* | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | called by mutect2, pindel, varscan2
- ACLY | c.890del p.G297Vfs*31 | Frame Shift Del (DEL) | VAF 35/124 reads (28%) | called by mutect2, pindel, varscan2
- ACP5 | c.841T>C p.F281L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- ACSL1 | c.589_590dup p.V198Wfs*14 | Frame Shift Ins (INS) | VAF 33/69 reads (48%) | called by mutect2, varscan2
- ACSM2B | c.424T>C p.S142P | Missense Mutation (SNP) | VAF 94/291 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAMTS9 | c.5498A>T p.D1833V | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2633C>T p.P878L | Missense Mutation (SNP) | VAF 16/470 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.096); called by muse, mutect2
- ADGRV1 | c.16395del p.F5465Lfs*13 | Frame Shift Del (DEL) | VAF 54/192 reads (28%) | called by pindel, varscan2
- ADSL | c.535C>A p.L179I | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- AFDN | c.1477del p.A493Rfs*25 | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | called by mutect2, pindel, varscan2
- AFDN | c.4106del p.P1369Rfs*29 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- AGGF1 | c.2042del p.N681Tfs*29 | Frame Shift Del (DEL) | VAF 72/232 reads (31%) | called by mutect2, varscan2
- AIFM3 | c.1345A>G p.I449V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AKAP6 | c.913G>T p.G305C | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2
- AKAP7 | c.715del p.I239* | Frame Shift Del (DEL) | VAF 25/67 reads (37%) | called by mutect2, varscan2
- AKAP9 | c.3721G>A p.E1241K | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ALDH1B1 | c.1085_1086del p.V362Gfs*6 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel
- ALKBH6 | c.163G>A p.G55R (on ENST00000252984 / NM_001297701.2; = p.G83R on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMER2 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- AMPH | c.1459del p.A487Pfs*19 | Frame Shift Del (DEL) | VAF 21/75 reads (28%) | called by mutect2, pindel, varscan2
- ANGPT2 | c.94A>G p.K32E | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANK1 | c.398del p.N133Mfs*7 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- ANK2 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKIB1 | c.1462dup p.I488Nfs*13 | Frame Shift Ins (INS) | VAF 5/28 reads (18%) | called by pindel, varscan2
- ANO4 | c.473G>T p.S158I (on ENST00000392977 / NM_001286615.2; = p.S123I on NM_178826.4) | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- APLNR | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.45); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- APOB | c.3565del p.M1189* | Frame Shift Del (DEL) | VAF 60/208 reads (29%) | called by mutect2, pindel, varscan2
- APOD | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ARAP2 | c.211del p.M71Cfs*34 | Frame Shift Del (DEL) | VAF 56/176 reads (32%) | called by mutect2, pindel, varscan2
- ARHGAP25 | c.1365del p.Q456Rfs*110 (on ENST00000409202 / NM_001007231.3; = p.Q448Rfs*110 on NM_014882.3) | Frame Shift Del (DEL) | VAF 41/144 reads (28%) | called by mutect2, pindel, varscan2
- ARHGAP32 | c.5123C>T p.A1708V (on ENST00000310343 / NM_001378025.1; = p.A1359V on NM_014715.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ARHGAP36 | c.1105-2A>G p.X369_splice | Splice Site (SNP) | VAF 136/414 reads (33%) | called by muse, mutect2, varscan2
- ARL14 | c.133A>T p.I45L | Missense Mutation (SNP) | VAF 95/259 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- ARMC9 | c.1936G>T p.G646W | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ARMCX1 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 152/441 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ARMCX2 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARMT1 | c.922A>G p.N308D | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ASB15 | c.442del p.L148Ffs*2 | Frame Shift Del (DEL) | VAF 42/139 reads (30%) | called by mutect2, pindel, varscan2
- ASIP | c.103A>C p.S35R | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ASNSD1 | c.1142C>A p.P381H | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ATG2B | c.5424del p.F1808Lfs*28 | Frame Shift Del (DEL) | VAF 90/242 reads (37%) | called by mutect2, varscan2
- ATG4B | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, varscan2
- ATP11C | c.2299C>T p.Q767* | Nonsense Mutation (SNP) | VAF 10/131 reads (8%) | called by muse, mutect2
- ATP1B2 | c.142del p.Y48Mfs*14 | Frame Shift Del (DEL) | VAF 38/116 reads (33%) | called by mutect2, pindel, varscan2
- ATP4A | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ATR | c.821dup p.L274Ffs*13 | Frame Shift Ins (INS) | VAF 30/107 reads (28%) | called by mutect2, pindel, varscan2
- BAG4 | c.1245G>A p.M415I | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- BCL2L11 | c.533A>G p.H178R (on ENST00000393256 / NM_138621.5; = p.H118R on NM_006538.5) | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- BCOR | c.4862del p.P1621Qfs*53 (on ENST00000378444 / NM_001123385.2; = p.P1587Qfs*53 on NM_017745.6) | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel
- BLM | c.3651del p.K1217Nfs*62 | Frame Shift Del (DEL) | VAF 57/162 reads (35%) | called by mutect2, pindel, varscan2
- BMPER | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 118/354 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- BMPR2 | c.967+1G>A p.X323_splice | Splice Site (SNP) | VAF 18/92 reads (20%) | called by muse, varscan2
- BPTF | c.8154del p.K2718Nfs*36 | Frame Shift Del (DEL) | VAF 53/187 reads (28%) | called by mutect2, pindel, varscan2
- BRINP1 | c.2219A>C p.H740P | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- BTNL8 | c.242A>G p.Y81C | Missense Mutation (SNP) | VAF 89/250 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C10orf90 | c.2014del p.R672Gfs*2 | Frame Shift Del (DEL) | VAF 43/132 reads (33%) | called by mutect2, pindel, varscan2
- C12orf40 | c.481T>C p.S161P | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- C1GALT1 | c.755T>C p.V252A | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C1QB | c.489dup p.G164Rfs*34 | Frame Shift Ins (INS) | VAF 50/164 reads (30%) | called by mutect2, pindel, varscan2
- C1R | c.689del p.P230Lfs*100 (on ENST00000536053 / NM_001354346.2; = p.P216Lfs*100 on NM_001733.7) | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | called by mutect2, pindel, varscan2
- C2orf15 | c.20A>T p.K7I | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1E | c.797A>G p.H266R | Missense Mutation (SNP) | VAF 93/298 reads (31%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CADM1 | c.1002del p.T335Qfs*42 | Frame Shift Del (DEL) | VAF 60/232 reads (26%) | called by pindel, varscan2
- CAMSAP2 | c.1206G>T p.Q402H (on ENST00000236925 / NM_001297707.2; = p.Q391H on NM_203459.3) | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CANX | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 112/332 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CAPN7 | c.785T>C p.V262A | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- CAPRIN2 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 18/404 reads (4%) | called by muse, mutect2
- CASP8 | c.716T>C p.I239T (on ENST00000432109 / NM_033355.3; = p.I256T on NM_001228.4) | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- CATSPER3 | c.860A>G p.Q287R | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBLL1 | c.1259del p.P420Lfs*20 | Frame Shift Del (DEL) | VAF 101/307 reads (33%) | called by mutect2, pindel, varscan2
- CCDC113 | c.578del p.N193Mfs*15 | Frame Shift Del (DEL) | VAF 24/98 reads (24%) | called by pindel, varscan2
- CCDC113 | c.607del p.M203Cfs*5 | Frame Shift Del (DEL) | VAF 28/96 reads (29%) | called by pindel, varscan2
- CCDC116 | c.796A>G p.I266V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.098); called by muse, mutect2
- CCDC125 | c.346T>C p.C116R | Missense Mutation (SNP) | VAF 58/217 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC160 | c.51del p.F17Lfs*7 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- CCDC28A | c.86T>C p.I29T | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.212); called by muse, varscan2
- CCDC66 | c.973A>G p.K325E (on ENST00000394672 / NM_001353147.1; = p.K291E on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- CCDC87 | c.1916del p.P639Hfs*3 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | called by mutect2, pindel, varscan2
- CCL2 | c.149G>T p.S50I | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCT2 | c.218del p.N73Tfs*12 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by pindel, varscan2
- CD4 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 116/448 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CDC37 | c.239A>G p.E80G | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH19 | c.692G>C p.G231A | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH8 | c.1048T>C p.S350P | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- CDHR3 | c.890G>T p.R297M | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CDKN3 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CDX4 | c.791C>A p.T264N | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CECR2 | c.2520del p.N841Tfs*59 (on ENST00000342247 / NM_001290047.2; = p.N658Tfs*59 on NM_001290046.1) | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel
- CEP152 | c.3749C>G p.A1250G (on ENST00000380950 / NM_001194998.2; = p.A1194G on NM_014985.4) | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- CERS2 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, varscan2
- CFHR5 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 26/400 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.55); called by muse, mutect2
- CGRRF1 | c.743del p.N248Tfs*35 | Frame Shift Del (DEL) | VAF 63/273 reads (23%) | called by mutect2, pindel, varscan2
- CIB1 | c.361G>T p.G121* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | called by muse, varscan2
- CKAP5 | c.2344A>G p.M782V | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- CLCC1 | c.526G>T p.D176Y (on ENST00000356970 / NM_001377464.1; = p.D126Y on NM_015127.5) | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- CLCN4 | c.1158del p.N387Ifs*36 | Frame Shift Del (DEL) | VAF 86/237 reads (36%) | called by mutect2, pindel, varscan2
- CLMN | c.2594del p.K865Rfs*10 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | called by mutect2, varscan2
- CLMP | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- CLSTN2 | c.1158dup p.H387Tfs*49 | Frame Shift Ins (INS) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- CNGA1 | c.555del p.F185Lfs*9 | Frame Shift Del (DEL) | VAF 48/170 reads (28%) | called by mutect2, pindel, varscan2
- CNKSR1 | c.210+2T>C p.X70_splice | Splice Site (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- CNKSR1 | c.2080del p.H694Tfs*16 (on ENST00000374253 / NM_001297647.2; = p.H687Tfs*16 on NM_006314.3) | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- CNOT9 | c.356del p.L119Cfs*29 | Frame Shift Del (DEL) | VAF 119/338 reads (35%) | called by mutect2, pindel, varscan2
- CNOT9 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 37/107 reads (35%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.2975C>A p.P992H | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COA8 | c.327A>C p.K109N | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- COL17A1 | c.4070C>T p.A1357V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- COPS2 | c.144del p.A49Rfs*3 | Frame Shift Del (DEL) | VAF 116/354 reads (33%) | called by mutect2, pindel, varscan2
- COX19 | c.270del p.K90Nfs*4 | Frame Shift Del (DEL) | VAF 22/69 reads (32%) | called by mutect2, pindel, varscan2
- CPEB1 | c.1136C>T p.P379L (on ENST00000617958; = p.P319L on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPNE3 | c.1500del p.E501Kfs*107 | Frame Shift Del (DEL) | VAF 85/278 reads (31%) | called by mutect2, pindel, varscan2
- CPNE6 | c.1081G>T p.G361C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPXCR1 | c.434G>A p.S145N | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTNND2 | c.1627A>G p.R543G | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CTTNBP2 | c.3006A>C p.K1002N | Missense Mutation (SNP) | VAF 57/243 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- CUL9 | c.2416T>C p.S806P | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYRIB | c.189A>G p.I63M | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DAAM2 | c.1113G>T p.E371D | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DAB1 | c.1258dup p.L420Pfs*9 (on ENST00000371231; = p.L387Pfs*9 on NM_021080.5 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | called by mutect2, varscan2
- DAB2 | c.1194del p.F398Lfs*15 | Frame Shift Del (DEL) | VAF 36/117 reads (31%) | called by mutect2, pindel, varscan2
- DACT1 | c.839G>A p.S280N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCAF6 | c.421_423del p.Y141del | In Frame Del (DEL) | VAF 94/313 reads (30%) | called by mutect2, pindel, varscan2
- DCC | c.1309C>A p.P437T | Missense Mutation (SNP) | VAF 64/491 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- DCLRE1B | c.1259del p.K420Rfs*3 | Frame Shift Del (DEL) | VAF 90/428 reads (21%) | called by mutect2, pindel, varscan2
- DCN | c.442dup p.M148Nfs*12 | Frame Shift Ins (INS) | VAF 66/242 reads (27%) | called by mutect2, varscan2
- DDIT3 | c.274C>G p.Q92E | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- DDX55 | c.1097del p.G366Afs*29 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | called by mutect2, pindel, varscan2
- DENND5A | c.3425G>A p.G1142D | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- DGKH | c.1748C>A p.A583D | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DHX16 | c.3097del p.I1033* | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | called by mutect2, pindel, varscan2
- DLG2 | c.1773G>T p.E591D | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.12); called by muse, mutect2
- DNAH3 | c.10513A>G p.T3505A | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- DNAH3 | c.422G>T p.R141M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH5 | c.216dup p.A73Cfs*37 | Frame Shift Ins (INS) | VAF 45/122 reads (37%) | called by mutect2, pindel, varscan2
- DNAH7 | c.2162del p.K721Rfs*5 | Frame Shift Del (DEL) | VAF 37/128 reads (29%) | called by mutect2, pindel, varscan2
- DNAJB5 | c.509del p.P170Qfs*21 | Frame Shift Del (DEL) | VAF 18/30 reads (60%) | called by mutect2, varscan2
- DOCK7 | c.3273del p.F1091Lfs*4 (on ENST00000635253 / NM_001367561.1; = p.F1060Lfs*4 on NM_033407.3) | Frame Shift Del (DEL) | VAF 89/273 reads (33%) | called by mutect2, pindel, varscan2
- DOCK7 | c.886-3del | Splice Region (DEL) | VAF 29/118 reads (25%) | called by mutect2, varscan2
- DPP4 | c.755T>C p.V252A | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- DSCAML1 | c.3227A>G p.N1076S (on ENST00000321322; = p.N1016S on NM_020693.4) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DSG3 | c.281A>G p.Q94R | Missense Mutation (SNP) | VAF 73/229 reads (32%) | SIFT tolerated (0.96); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DTWD2 | c.309+2T>C p.X103_splice | Splice Site (SNP) | VAF 147/213 reads (69%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.5705del p.G1902Vfs*27 | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.7609T>G p.Y2537D | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
662 further variants in this file (346 protein-altering or splice-affecting, 293 silent, 23 other) are not listed here.
